Surgical pathology report (de-identified scan), TCGA case TCGA-61-1998, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1998-01A (Primary Tumor).

PART 1: BLADDER FLAP, BIOPSY -
METASTATIC ADENOCARCINOMA.

PART 2: RECTOVAGINAL SEPTUM NODULE, EXCISION -
METASTATIC ADENOCARCINOMA (2 CM).

PART 3: UTERUS WITH CERVIX, BILATERAL ADNEXA, RECTOSIGMOID COLON, AND PORTION OF BLADDER, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY, PARTIAL COLECTOMY, AND EXCISION -

- A. RIGHT ADNEXA WITH PAPILLARY SEROUS ADENOCARCINOMA (12 CM).
- B. THE RIGHT ADNEXAL MASS IS ADHERENT TO THE UTERUS AND COLON; THE COLON IS ALSO ADHERENT TO THE UTERUS.
- C. ADENOCARCINOMA IS ASSOCIATED WITH PSAMMOMA BODY CALCIFICATIONS.
- D. LYMPHOVASCULAR SPACE INVASION IS PRESENT.
- E. CAPSULE IS NOT INTACT; TUMOR OBLITERATES THE RIGHT ADNEXA (NO RESIDUAL RIGHT OVARIAN TISSUE IDENTIFIED).
- F. REMNANT OF RIGHT FALLOPIAN TUBE TISSUE IS ADHERENT TO TUMOR.
- G. LEFT OVARY WITH ADENOCARCINOMA DEPOSITS (3 CM) AND BENIGN SIMPLE CYST WITH DENUDED LINING (8 CM).
- H. LEFT FALLOPIAN TUBE WITH TUMOR NODULES MEASURING UP TO APPROXIMATELY 1 CM.
- I. APPARENT BLADDER FLAP TISSUE WITH METASTATIC ADENOCARCINOMA; NO BLADDER MUCOSA IS IDENTIFIED.
- J. UTERUS WITH SEROSAL INVOLVEMENT BY TUMOR INVADING TO A DEPTH OF APPROXIMATELY 0.2 CM WITH LYMPHOVASCULAR SPACE INVASION DEEP TO THE TUMOR INVASION.
- K. WEAKLY PROLIFERATIVE ENDOMETRIUM, ENDOMETRIUM IS NEGATIVE FOR TUMOR.
- L. CERVIX IS NEGATIVE FOR TUMOR.
- M. LEIOMYOMATA.
- N. COLON WITH INVOLVEMENT BY NUMEROUS NODULES OF METASTATIC ADENOCARCINOMA THAT INVADE INTO THE MUSCULARIS PROPRIA BUT DO NOT INVOLVE THE COLONIC MUCOSA.
- O. COLONIC MUCOSA WITH TUBULAR ADENOMAS.
- P. COLONIC DISTAL AND PROXIMAL MARGINS ARE NEGATIVE FOR TUMOR.
- Q. PATHOLOGIC STAGE: pT3c pN1 pMX (FIGO STAGE: IIIC).

PART 4: RIGHT COMMON ILIAC LYMPH NODE, BIOPSY -

- A. TWO (2) LYMPH NODES, POSITIVE FOR METASTATIC ADENOCARCINOMA MEASURING UP TO 1.5 MM.
- B. NO EXTRACAPSULAR EXTENSION IS PRESENT.

PART 5: LEFT COMMON ILIAC LYMPH NODE, BIOPSY -

ONE (1) LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 6: APPENDIX, APPENDECTOMY -

APPENDIX WITH SEROSAL ADHESIONS, NEGATIVE FOR NEOPLASM.

PART 7: DIAPHRAGM NODULES, EXCISION -

METASTATIC ADENOCARCINOMA, MEASURING UP TO APPROXIMATELY 1 CM.

PART 8: OMENTUM, OMENTECTOMY -

OMENTUM WITH APPROXIMATELY 80% DIFFUSE INVOLVEMENT BY METASTATIC ADENOCARCINOMA (OMENTUM MEASURED 10 CM).

PART 9: LEFT EXTERNAL ILIAC LYMPH NODE, BIOPSY -

- A. ONE (1) LYMPH NODE, POSITIVE FOR METASTATIC ADENOCARCINOMA (1/2).
- B. TUMOR MEASURES 0.5 CM; NO EXTRACAPSULAR EXTENSION WAS PRESENT.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	Other: Colectomy and debulking
TUMOR SIZE:	Maximum dimension: 10 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC GRADE (serous tumors):	High grade
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 5
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 2 Number of positive lymph nodes, Left: 1
LYMPH NODE GROUPS INVOLVED:	Common iliac, Right, External iliac, Left

EXTRANODAL EXTENSION: No

T STAGE, PATHOLOGIC: T STAGE, PATHOLOGIC** continued on next page
T STAGE, PATHOLOGIC** continued

N STAGE, PATHOLOGIC: pT3c
pN1

Source: NCI Genomic Data Commons file 24cb4bd0-cb07-4396-bc3d-0ade130dd7cc (TCGA-61-1998.788D25C6-75C4-4C85-BE93-98DEC021219A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).